Gene-level copy-number profile of tumor specimen ALCH-B4AC-TTP1-A from ALCHEMIST case ALCH-B4AC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.6 years (21,056 days).
Specimen ALCH-B4AC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8e8cf97-4f1b-4bef-8e24-52f4a877360e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4AC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/6eff3c7e-b2bd-4fe9-befb-05965813d1e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 14,709; copy number 2: 40,570; copy number 3: 2,573; copy number 4: 137; copy number 5: 86; copy number 6: 173; copy number 7: 30; copy number 9: 103; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:17,717,625–17,749,978, 1 gene (within-gene range 0–1): LINC02810.
- chr3:52,794,768–52,809,009, 1 gene: ITIH3.
- chr9:28,888,879–28,888,955, 1 gene: MIR873.
- chr11:113,450,023–113,450,088, 1 gene (within-gene range 0–1): MIR4301.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 393 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,455,568–166,570,763, 19 genes, copy number 5: AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326.
- chr3:169,083,499–185,281,990, 289 genes, copy number 5–9 (broad region; genes not listed).
- chr7:74,773,962–74,851,551, 2 genes, copy number 5–15: NCF1, GTF2IRD2.
- chr7:74,906,673–74,913,310, 1 gene, copy number 9: SPDYE12P.
- chr8:43,672,823–43,674,591, 2 genes, copy number 5: AC139365.2, AC139365.1.
- chr11:68,941,503–70,436,584, 47 genes, copy number 6: AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:71,382,601–71,863,658, 30 genes, copy number 7: ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, RPS3AP41, ALG1L9P, SNRPCP14, AP003498.1, ENPP7P8, AP003498.2, FAM86C1P, ALG1L9P, ZNF705E, DEFB108B, RNA5SP342, DEFB130C.
- chr14:105,583,731–105,588,395, 1 gene, copy number 6: IGHA2.
- chr15:92,819,540–92,899,701, 1 gene, copy number 5 (within-gene range 2–5): CHASERR.
- chr17:59,847,438–59,847,544, 1 gene, copy number 5: RNU6-450P.

Autosomal genes at a single copy (total copy number 1): 12,440. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
